FM case AD10786 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/e6d61596-d43e-44b4-8932-d817877a2141

Male, 67.6 years: Merkel cell carcinoma (ICD-O-3 8247/3) of the skin; metastasis biopsied or resected from the connective, subcutaneous and other soft tissues. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
